Surgical pathology report (de-identified scan), TCGA case TCGA-IE-A6BZ, project TCGA-SARC (Sarcoma), tissue source site ABS - IUPUI, specimen TCGA-IE-A6BZ-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Sarcoma, undifferentiated,
pleomorphic 8805/3

Site: Connective, subcutaneous
and other soft tissue of
buttock C49.5

Operative Procedure:

Excision mass right buttocks.

Specimen Received:

Right buttock mass; stitch at proximal margin

Final Pathologic Diagnosis:

Soft tissue, right buttock, mass, resection:

Undifferentiated pleomorphic sarcoma ("malignant fibrous histiocytoma") --
see synoptic report

Procedure: Excisional mass, right buttock
Tumor site: Right buttock
Tumor size: 19 x 11 x 8 cm
Macroscopic extent of tumor: Deep
Histologic type: Undifferentiated pleomorphic sarcoma
Mitotic rate: 15/10 corrected high-power fields (HPF)
Necrosis: Present (extent: 30%)
Histologic grade: High grade
Margins: Unspecified peripheral margin involved (slide 3)
0.3 cm from distal margin
Proximal margin is uninvolved

Pathologic staging (pTNM)

TNM descriptors: None known
Primary tumor: pT2b
Regional lymph nodes: pNX
Number examined: 0
Number involved: Not applicable
Distant metastasis: pM not applicable

Additional pathologic findings: None identified

Ancillary studies

Immunohistochemistry: Not performed
Cytogenetics: Not performed
Molecular pathology: Not performed

Radiographic findings: Not available

Preresection treatment: Unknown

Treatment effect: Not identified

The examination of this case material and the preparation of this report were
performed by the staff pathologist.

Hx/AA Discrepancy		
Print Malignancy Discrepancy		
Dr. [Signature] Discrepancy		
Case # [Signature]		
Reviser Initials		

hw 5/10/13

[page 2 of 2]
Gross Description:

Received in formalin, labeled "right buttock mass" is a 24 x 21 x 11 cm tan, lobulated irregular fibrofatty soft tissue with attached suture designating proximal margin. The specimen is inked and step sectioned revealing a 19 x 11 x 8 cm tan, soft lobulated heterogeneous well delineated, focally hemorrhagic/necrotic (30%) mass, which abuts the nearest peripheral margin, coming to within 0.9 cm from the distal margin and 2 cm from the proximal margin. The remaining cut surface consists of tan, lobulated fat and tan to red, homogeneous muscle.

Representative sections are submitted as follows:

- 1 proximal margin taken perpendicular;
- 2 mass to distal margin;
- 3-12 random mass (inked resection margin in cassettes 3-5).

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age:) Gender: F

Source: NCI Genomic Data Commons file 9085c50e-e0ec-4530-92d5-eb5faf120dfe (TCGA-IE-A6BZ.1E3F33F0-2F87-4CD9-838C-966722D7E0A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).